Somatic mutation profile of tumor specimen TARGET-20-PASIEP-09A (aliquot TARGET-20-PASIEP-09A-02D) from TARGET case TARGET-20-PASIEP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.7 years (6,082 days).
Specimen TARGET-20-PASIEP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26e4d7d7-3116-4b3e-97e5-70da6ef39ffb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASIEP-14A (Bone Marrow Normal), aliquot TARGET-20-PASIEP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08296a1e-2604-4d10-88d8-93619d1ed997

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.68dup p.H24Afs*84 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | catalogued as rs137852728, COSV57196009, COSV57200435; ClinVar: pathogenic; called by mutect2, varscan2
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 36/81 reads (44%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
